Somatic mutation profile of tumor specimen TCGA-DD-A1EK-01A (aliquot TCGA-DD-A1EK-01A-11D-A20W-10) from TCGA case TCGA-DD-A1EK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 64.2 years (23,437 days).
Specimen TCGA-DD-A1EK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e3d71f3-27f7-4ad3-8e90-d8def208cd7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1EK-10A (Blood Derived Normal), aliquot TCGA-DD-A1EK-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ada4474f-325e-4f18-b947-5217bb45f29f

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 13, Nonsense Mutation 4, Splice Site 4, Frame Shift Ins 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAK1 | c.860A>T p.H287L | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV68642252; called by muse, mutect2, varscan2
- ACSL1 | c.256T>A p.Y86N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV55662839; called by muse, mutect2, varscan2
- ACVR1C | c.1438A>G p.K480E | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54646402; called by muse, mutect2, varscan2
- ADAM21 | c.960T>G p.I320M | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV50794390; called by muse, mutect2, varscan2
- ADAMTS9 | c.4334G>A p.W1445* | Nonsense Mutation (SNP) | VAF 50/129 reads (39%) | catalogued as COSV55781541; called by muse, mutect2, varscan2
- ADCY6 | c.1490A>G p.N497S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1446810799, COSV57168063; called by muse, mutect2, varscan2
- ANO9 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs139380371; called by muse, mutect2, varscan2
- AOX1 | c.1511T>G p.L504W | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV65981758; called by muse, mutect2, varscan2
- AP3S1 | c.458G>C p.G153A | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV57474905, COSV57476919; called by muse, mutect2, varscan2
- APBB2 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.122); catalogued as COSV55952834; called by muse, mutect2, varscan2
- APOB | c.8670C>A p.F2890L | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV51936647; called by muse, mutect2, varscan2
- ARMCX1 | c.416C>A p.A139E | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV65705186; called by muse, mutect2, varscan2
- ASCC2 | c.462C>A p.F154L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV57073949; called by muse, mutect2, varscan2
- BIRC6 | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV70199556; called by muse, mutect2, varscan2
- BTAF1 | c.1318C>G p.Q440E | Missense Mutation (SNP) | VAF 135/339 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV56434399; called by muse, mutect2, varscan2
- C7 | c.2407A>T p.S803C | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as COSV57474740; called by muse, mutect2, varscan2
- CEP120 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.196); catalogued as COSV60265630; called by muse, mutect2, varscan2
- CHD4 | c.3881A>G p.E1294G (on ENST00000357008 / NM_001363606.2; = p.E1307G on NM_001273.5) | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV58901543; called by muse, mutect2, varscan2
- CNTNAP3 | c.2944G>T p.V982F | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs779868839, COSV52668218; called by muse, mutect2, varscan2
- COL6A6 | c.1847G>T p.C616F | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62025938; called by muse, mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 14/145 reads (10%) | catalogued as rs767756120; called by mutect2, varscan2
- DACT1 | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100241624, COSV60020889; called by muse, mutect2
- DCAF4L2 | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60478916; called by muse, mutect2, varscan2
- E2F6 | c.380+1G>C p.X127_splice | Splice Site (SNP) | VAF 36/105 reads (34%) | catalogued as COSV56215850; called by muse, mutect2, varscan2
- EGFR | c.3448A>T p.T1150S | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51801820; called by muse, mutect2, varscan2
- EHHADH | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51630353; called by muse, mutect2
- FLOT1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV52543934; called by muse, mutect2, varscan2
- IDUA | c.300-2A>T p.X100_splice | Splice Site (SNP) | VAF 77/190 reads (41%) | catalogued as COSV56103421; called by muse, mutect2, varscan2
- KIF1A | c.1179C>G p.D393E | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV57490182; called by muse, mutect2, varscan2
- KRT27 | c.1035G>T p.Q345H | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV56971960, COSV56973208; called by muse, mutect2, varscan2
- LRFN5 | c.1275A>T p.E425D | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV53257405; called by muse, mutect2, varscan2
- MRPS33 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV61341280; called by muse, mutect2, varscan2
- NT5C3A | c.931G>T p.D311Y (on ENST00000610140 / NM_001374335.1; = p.D277Y on NM_016489.13) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54237279, COSV54238339; called by muse, mutect2, varscan2
- PTPN9 | c.769C>G p.H257D | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.236); catalogued as COSV60723759; called by muse, mutect2, varscan2
- RAPH1 | c.3121C>T p.L1041F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1187023876, COSV55584132; called by muse, mutect2, varscan2
- RBM19 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 86/239 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs776232799, COSV55692435, COSV99926957; called by muse, mutect2, varscan2
- RNF123 | c.1557+1G>A p.X519_splice | Splice Site (SNP) | VAF 59/156 reads (38%) | catalogued as rs752488889, COSV59687369; called by muse, mutect2, varscan2
- SLC2A4RG | c.580-2A>G p.X194_splice | Splice Site (SNP) | VAF 24/83 reads (29%) | catalogued as COSV55510314; called by muse, mutect2, varscan2
- SLC6A17 | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs141622274; called by muse, mutect2, varscan2
- SSMEM1 | c.25T>G p.W9G | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV52833546; called by muse, mutect2, varscan2
- TAF2 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100978536, COSV65418318; called by muse, mutect2, varscan2
- TCHH | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 67/288 reads (23%) | catalogued as COSV64272508, COSV64274987; called by muse, mutect2, varscan2
- TGFA | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); catalogued as COSV54913781; called by muse, varscan2
- TLX3 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV51540044; called by muse, mutect2, varscan2
- TNNT2 | c.883G>A p.G295R (on ENST00000236918; = p.G292R on NM_000364.4) | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs147940106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSC1 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 55/84 reads (65%) | catalogued as COSV53767176; called by muse, mutect2, varscan2
- UBR2 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV65750258; called by muse, mutect2, varscan2
- ZNF20 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs761462185, COSV61999465; called by muse, mutect2, varscan2
- LRRC3 | c.112dup p.R38Pfs*4 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- ATP7B | c.993C>T p.A331= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs377294197; called by muse, mutect2, varscan2
- CCNQ | c.633C>A p.V211= | Silent (SNP) | VAF 70/145 reads (48%) | catalogued as COSV52344441; called by muse, mutect2, varscan2
- DSCAM | c.948C>A p.A316= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV68027109; called by muse, mutect2, varscan2
- EIF2D | c.1065C>T p.F355= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as rs114245341, COSV55113689; called by muse, mutect2, varscan2
- ERF | c.417T>G p.G139= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV55896067; called by muse, mutect2, varscan2
- GFRAL | c.312A>G p.K104= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs777786050, COSV61231166; called by muse, mutect2, varscan2
- PCDHA8 | c.1362G>A p.A454= | Silent (SNP) | VAF 126/311 reads (41%) | catalogued as COSV65337296; called by muse, mutect2, varscan2
- PCLO | c.9387A>C p.S3129= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as rs776093952, COSV61636783; called by muse, mutect2, varscan2
- SELE | c.1419T>C p.L473= | Silent (SNP) | VAF 88/287 reads (31%) | catalogued as rs761064301, COSV60975689; called by muse, mutect2, varscan2
- SRRM2 | c.4443T>C p.D1481= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV57073574; called by muse, mutect2, varscan2
- STAU2 | c.216A>G p.E72= (on ENST00000524300 / NM_001164380.2; = p.E40= on NM_014393.2) | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV62475847; called by muse, mutect2, varscan2
- UNC5A | c.1797G>A p.A599= | Silent (SNP) | VAF 42/76 reads (55%) | catalogued as rs1380046859, COSV52840296; called by muse, mutect2, varscan2
- UTS2R | c.426C>A p.T142= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV100493251, COSV57452885; called by muse, mutect2, varscan2
- ATG2A | chr11:64891436 A>C | 3'Flank (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- MYH9 | c.612+1472A>T | Intron (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99338916; called by muse, mutect2, varscan2
